Somatic mutation profile of tumor specimen TCGA-AC-A23C-01A (aliquot TCGA-AC-A23C-01A-12D-A167-09) from TCGA case TCGA-AC-A23C, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.3 years (22,751 days).
Specimen TCGA-AC-A23C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce4efe10-ee67-46db-acdc-4e58bb8463b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A23C-10A (Blood Derived Normal), aliquot TCGA-AC-A23C-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39ee0a7a-9af5-494e-a291-7cf8e11a24e7

The open-access MAF lists 122 somatic variants for this specimen: 94 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 26, Frame Shift Del 7, Nonsense Mutation 5, Splice Site 2, Nonstop Mutation 1, RNA 1, Splice Region 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.4946A>T p.K1649M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs760817875, COSV60931425; called by muse, mutect2, varscan2
- AIM2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.748); catalogued as COSV63702120; called by muse, mutect2, varscan2
- BCS1L | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55306125, COSV55309811; called by muse, mutect2, varscan2
- CACNA1F | c.5591A>G p.Y1864C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100544235; called by muse, mutect2
- CAD | c.1333G>T p.G445W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53032150; called by muse, mutect2, varscan2
- CADM2 | c.716A>C p.Q239P (on ENST00000407528 / NM_001167674.2; = p.Q241P on NM_153184.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV67405504; called by muse, mutect2, varscan2
- CD1E | c.391A>T p.M131L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100936876; called by muse, mutect2
- CDK14 | c.199G>A p.E67K (on ENST00000380050 / NM_001287135.2; = p.E49K on NM_012395.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV56052777; called by muse, mutect2, varscan2
- CEP162 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV57624875; called by muse, mutect2, varscan2
- CEP20 | c.503T>G p.V168G | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV55385198; called by muse, mutect2, varscan2
- CLSTN2 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757739003, COSV71720917; called by muse, mutect2, varscan2
- COL6A6 | c.4622C>A p.P1541H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.343); catalogued as COSV62025342; called by muse, mutect2, varscan2
- CUL2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1375537047, COSV66079394; called by muse, mutect2
- DCUN1D1 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV53046226; called by muse, mutect2, varscan2
- DDX53 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs769123385, COSV60069171; called by muse, mutect2
- DGKQ | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56619797; called by muse, mutect2, varscan2
- DNAJC14 | c.118_119del p.R40Gfs*8 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as COSV57914472; called by mutect2, pindel, varscan2
- DOCK2 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56956201, COSV56956684; called by muse, mutect2, varscan2
- DOCK4 | c.4255G>A p.D1419N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV70243377; called by muse, mutect2, varscan2
- DPY19L1 | c.1862G>A p.R621K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.76); catalogued as COSV100204389; called by muse, mutect2, varscan2
- ETS1 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV67009156; called by muse, mutect2, varscan2
- F9 | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99496177; called by muse, mutect2
- FAM126A | c.744T>C p.F248= | Splice Region (SNP) | VAF 8/49 reads (16%) | catalogued as COSV101326987; called by muse, mutect2
- FAM47A | c.1300T>C p.S434P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60499959; called by muse, mutect2, varscan2
- FER1L6 | c.2004G>C p.W668C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV67552896; called by muse, mutect2, varscan2
- FGD6 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.533); catalogued as COSV59693067; called by muse, mutect2
- FMN2 | c.2063C>A p.T688N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV100142003; called by muse, mutect2
- FMR1 | c.175A>C p.I59L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV54427614; called by muse, varscan2
- GOLGB1 | c.7573G>C p.E2525Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); catalogued as COSV100510178; called by muse, mutect2
- HDAC2 | c.1465T>A p.*489Rext*2 | Nonstop Mutation (SNP) | VAF 7/99 reads (7%) | catalogued as COSV100892522; called by muse, mutect2
- HDHD2 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV56077139; called by muse, mutect2, varscan2
- HEATR1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as COSV63979518, COSV63979583; called by muse, mutect2, varscan2
- HNRNPDL | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99786973; called by muse, mutect2
- ICA1L | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100841630; called by muse, mutect2
- INPPL1 | c.1408G>C p.G470R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53359524; called by muse, mutect2, varscan2
- KCNS3 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.285); catalogued as COSV58408961; called by muse, mutect2, varscan2
- KCNT2 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1015355622, COSV54109856; called by muse, mutect2, varscan2
- LNX1 | c.1693G>A p.E565K (on ENST00000263925 / NM_001126328.3; = p.E469K on NM_032622.2) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV55783592; called by muse, mutect2, varscan2
- LRRIQ4 | c.1454A>G p.E485G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV61620305; called by muse, mutect2, varscan2
- LYZL2 | c.223A>G p.K75E (on ENST00000375318; = p.K29E on NM_183058.3) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV64685083; called by muse, mutect2, varscan2
- MAP2 | c.4259C>T p.S1420L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1387562937, COSV99557238; called by muse, mutect2
- MED12 | c.4141A>T p.N1381Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV61356337; called by muse, mutect2, varscan2
- MUC2 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); catalogued as COSV61249837; called by muse, mutect2, varscan2
- N4BP1 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV52213421, COSV52213529; called by muse, mutect2, varscan2
- NBPF9 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs1207249441; called by muse, mutect2, varscan2
- NCOR1 | c.5374C>T p.Q1792* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV51996750; called by muse, mutect2, varscan2
- NF1 | c.2147A>T p.E716V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62222325; called by muse, mutect2, varscan2
- NPY1R | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.274); catalogued as COSV56714123; called by muse, mutect2, varscan2
- NSMCE1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as COSV100814822; called by muse, mutect2
- PALM2AKAP2 | c.2567A>G p.E856G (on ENST00000259318 / NM_001136562.3; = p.E1100G on NM_007203.5) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV52181725; called by muse, mutect2, varscan2
- PDE10A | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV63106518; called by muse, mutect2, varscan2
- POF1B | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV53140827; called by muse, mutect2, varscan2
- PPP5C | c.1385T>C p.I462T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50144690; called by muse, mutect2, varscan2
- PTPRO | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as rs761583283, COSV55522285; called by muse, mutect2, varscan2
- RAB3IL1 | c.372G>C p.K124N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.876); catalogued as COSV57119067; called by muse, mutect2, varscan2
- RBBP7 | c.1209+1G>T p.X403_splice | Splice Site (SNP) | VAF 14/53 reads (26%) | catalogued as COSV58113444; called by muse, mutect2, varscan2
- SIX4 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV53671639; called by muse, mutect2, varscan2
- SLC24A4 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs778472920, COSV54107783; called by muse, mutect2, varscan2
- SLC9A8 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV64291558; called by muse, mutect2, varscan2
- SLFN11 | c.2156C>G p.S719* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs1205676518, COSV57700629; called by muse, mutect2, varscan2
- SMC3 | c.3191G>A p.G1064D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV62422458; called by muse, mutect2, varscan2
- SS18 | c.199T>A p.S67T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52264036; called by muse, mutect2, varscan2
- SYBU | c.1081G>A p.D361N (on ENST00000276646 / NM_001099754.2; = p.D360N on NM_017786.6) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52621593; called by muse, mutect2
- TACC3 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV57608123; called by muse, mutect2, varscan2
- TBC1D4 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV66492362; called by muse, mutect2, varscan2
- TBC1D8 | c.2743G>C p.E915Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV65216839; called by muse, mutect2, varscan2
- TBX22 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1407601790, COSV64784842; called by muse, mutect2, varscan2
- TCAIM | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100703113; called by muse, mutect2
- TLN1 | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV59211922; called by muse, mutect2, varscan2
- TMCO2 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV65647038; called by muse, mutect2, varscan2
- TP53 | c.522del p.R174Sfs*73 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as COSV52773028, COSV52839726, COSV53424551; called by mutect2, pindel, varscan2
- TRIM23 | c.959G>T p.W320L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV51554690; called by muse, mutect2, varscan2
- TRIO | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV60096383; called by muse, mutect2, varscan2
- TTC37 | c.2578-1G>T p.X860_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV62456983; called by muse, mutect2, varscan2
- USP33 | c.318C>A p.N106K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62471585; called by muse, mutect2, varscan2
- USP51 | c.1457A>G p.Q486R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.196); catalogued as rs1355013240, COSV72351996; called by muse, mutect2, varscan2
- VWCE | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs927814868, COSV57112142; called by muse, mutect2, varscan2
- XKR7 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1484142377, COSV73813181, COSV73813483; called by muse, mutect2, varscan2
- ZFYVE19 | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.01); catalogued as COSV54542253; called by muse, mutect2, varscan2
- ZMYM5 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61989751; called by muse, mutect2, varscan2
- ZNF274 | c.1588A>G p.T530A (on ENST00000610905; = p.T425A on NM_016324.3) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV58767078; called by muse, mutect2, varscan2
- ZNF544 | c.2035C>T p.H679Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV54138535; called by muse, mutect2, varscan2
- ZNF786 | c.1917C>A p.H639Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60277731; called by muse, mutect2, varscan2
- ZNF883 | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV71309250; called by muse, mutect2, varscan2
- ZPBP2 | c.902C>T p.P301L (on ENST00000348931 / NM_199321.3; = p.P279L on NM_198844.3) | Missense Mutation (SNP) | VAF 214/283 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569519813, COSV62375772; called by muse, varscan2
- ZPBP2 | c.974C>G p.S325C (on ENST00000348931 / NM_199321.3; = p.S303C on NM_198844.3) | Missense Mutation (SNP) | VAF 206/287 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs548838743, COSV62375779; called by muse, varscan2
- AP3M2 | c.900_936del p.M301Rfs*7 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel
- EP400 | c.2584_2586del p.E862del | In Frame Del (DEL) | VAF 10/28 reads (36%) | called by pindel, varscan2
- GLG1 | c.2499_2500del p.F833Lfs*32 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- MAN2A2 | c.870del p.F291Lfs*20 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- PTEN | c.547_548del p.K183Efs*6 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- TAF2 | c.354C>A p.D118E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); called by muse, mutect2
- ZNF462 | c.6916_6919del p.T2306Sfs*13 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTSL3 | c.3837G>A p.L1279= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV54470351; called by muse, mutect2, varscan2
- AHRR | c.780C>T p.L260= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs374703194; called by muse, mutect2, varscan2
- ALPK3 | c.363T>C p.C121= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV51940076; called by muse, mutect2, varscan2
- ANGPTL5 | c.234C>T p.F78= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100527710, COSV57534628; called by muse, mutect2, varscan2
- ATP1A4 | c.213T>C p.H71= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV63628640; called by muse, mutect2, varscan2
- CENPF | c.4344C>A p.V1448= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV65279224; called by muse, mutect2, varscan2
- CHD6 | c.5670A>C p.V1890= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV64692898, COSV64694628; called by muse, mutect2, varscan2
- DNMBP | c.1986C>G p.L662= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV60633396; called by muse, mutect2
- EDA2R | c.306A>G p.Q102= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV53633125; called by muse, mutect2, varscan2
- FAM234B | c.126G>A p.Q42= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV52197690; called by muse, mutect2, varscan2
- FMOD | c.954C>G p.L318= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100724460; called by muse, mutect2
- GPAM | c.1599A>C p.V533= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV62082665; called by muse, mutect2, varscan2
- H2BC15 | c.84G>A p.K28= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs766426531, COSV100356912, COSV57586617; called by muse, mutect2, varscan2
- KIF14 | c.4125C>T p.I1375= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as COSV100950547, COSV66262599; called by muse, mutect2
- MTMR10 | c.2052C>G p.L684= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV58729913; called by muse, mutect2, varscan2
- OR6C76 | c.639C>G p.L213= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV60390098; called by muse, mutect2, varscan2
- PDE4DIP | c.3240C>T p.G1080= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs146755927; called by mutect2, varscan2
- SIPA1L3 | c.2373C>A p.V791= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1293495770, COSV99726844; called by muse, mutect2
- TAB3 | c.408C>T p.N136= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV55841097; called by muse, mutect2, varscan2
- TAOK1 | c.24C>T p.G8= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV55599049; called by muse, mutect2, varscan2
- TMPRSS6 | c.429C>T p.F143= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV60984048; called by muse, mutect2, varscan2
- TPTE2 | c.1203C>T p.F401= (on ENST00000400230 / NM_199254.2; = p.F324= on NM_130785.3) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99689452; called by muse, mutect2
- UHRF1BP1 | c.750C>T p.L250= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs775554517, COSV51960723; called by muse, mutect2, varscan2
- USP47 | c.2058C>T p.G686= (on ENST00000399455 / NM_001372095.1; = p.G598= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs368349531; called by muse, mutect2, varscan2
- USP6NL | c.1524T>G p.G508= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV53215872; called by muse, mutect2, varscan2
- ZNF98 | c.37T>C p.L13= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as COSV100757230; called by muse, mutect2
- ASIC3 | c.*86A>G | 3'UTR (SNP) | VAF 7/55 reads (13%) | catalogued as COSV52525958; called by muse, mutect2, varscan2
- TCP10L3 | n.264G>A | RNA (SNP) | VAF 4/32 reads (13%) | catalogued as rs767876675, COSV64751444; called by muse, mutect2, varscan2
